Somatic mutation profile of tumor specimen 0DU08X from CCDI case PBCHYP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Choroid plexus carcinoma; Tissue or organ of origin: Brain stem; Age at diagnosis: 0.4 years (162 days).
Specimen 0DU08X: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f543de7e-d7ad-42bd-a3f8-cc6560dd6484.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU07J (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6acfb6d9-36dc-4db5-bfa8-1837d2200c69

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Nonsense Mutation 1, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DENND6A | c.647C>A p.A216D | Missense Mutation (SNP) | VAF 32/805 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.111); catalogued as COSV60767551; called by muse, mutect2
- HCN1 | c.1768C>T p.R590* | Nonsense Mutation (SNP) | VAF 21/625 reads (3%) | catalogued as COSV100301761, COSV57491725, COSV57514836; called by muse, mutect2
- SAMD13 | c.206C>G p.A69G (on ENST00000370671; = p.A63G on NM_001010971.3) | Missense Mutation (SNP) | VAF 72/1381 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.331); called by muse, mutect2
- BTK | chrX:101390515 C>A | 5'Flank (SNP) | VAF 46/554 reads (8%) | called by muse, mutect2
- PHB2 | c.213-89C>T | Intron (SNP) | VAF 4/52 reads (8%) | catalogued as rs1350090238; called by muse, mutect2
